Somatic mutation profile of tumor specimen TARGET-20-PASLHH-09A (aliquot TARGET-20-PASLHH-09A-01D) from TARGET case TARGET-20-PASLHH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,229 days).
Specimen TARGET-20-PASLHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9347340-0a06-43f7-bf8c-d60002e6e2c7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLHH-14A (Bone Marrow Normal), aliquot TARGET-20-PASLHH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c8c3446-60ed-4ef0-9476-2a20950545e7

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs869312885, CM166270, COSV58783610, COSV58786816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.907_912dup p.A303_K304dup | In Frame Ins (INS) | VAF 42/99 reads (42%) | catalogued as COSV57196793, COSV57196937, COSV57200730; called by mutect2, varscan2
- CEBPA | c.201dup p.I68Hfs*40 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | catalogued as COSV57197957, COSV57198510; called by mutect2, pindel, varscan2
- TRIM24 | c.2728C>T p.R910C (on ENST00000343526 / NM_015905.3; = p.R876C on NM_003852.4) | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58968992; called by muse, mutect2, varscan2
